Somatic mutation profile of tumor specimen TCGA-J4-A6G1-01A (aliquot TCGA-J4-A6G1-01A-11D-A30X-08) from TCGA case TCGA-J4-A6G1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.3 years (24,945 days).
Specimen TCGA-J4-A6G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 163d6513-6937-4461-a70a-b02b2a8f1911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A6G1-10A (Blood Derived Normal), aliquot TCGA-J4-A6G1-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42865097-4fff-45ad-9f78-214fbdb14504

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX8 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV52252681; called by muse, mutect2
- FCGR2A | c.632G>T p.G211V (on ENST00000271450 / NM_001136219.3; = p.G210V on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54838270; called by muse, mutect2
- FLG | c.10542C>G p.D3514E | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as COSV64240275; called by muse, mutect2
- IFT27 | c.58G>A p.A20T (on ENST00000433985 / NM_001363003.2; = p.A19T on NM_006860.5) | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as rs775878094, COSV61416202; called by muse, mutect2
- RBM17 | c.1066T>C p.F356L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV65913834; called by muse, mutect2
- SYT11 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759130814, COSV64174041; called by muse, mutect2, varscan2
- TBC1D2 | c.2117A>C p.N706T | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV59784291; called by muse, mutect2
- TAB3 | c.997dup p.Y333Lfs*7 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- GATAD2A | c.18C>T p.C6= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1158284963, COSV53068737; called by muse, mutect2
- HYAL1 | c.72C>A p.G24= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV56497326; called by muse, mutect2
- NEU2 | c.1116C>A p.A372= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as COSV52092466; called by muse, mutect2
